Somatic mutation profile of tumor specimen MP2PRT-PASRCI-TMP1-A (aliquot MP2PRT-PASRCI-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASRCI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (725 days).
Specimen MP2PRT-PASRCI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c1bd646-2933-4a45-aff8-c24b4d02d88f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRCI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRCI-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e01ef56e-750a-4a9d-b580-9805714b2b86

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Frame Shift Ins 2, Silent 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.3200C>T p.A1067V | Missense Mutation (SNP) | VAF 100/146 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as rs750998195; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- IL10RB | c.524T>G p.F175C | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV99270255; called by muse, mutect2
- MYO1D | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 136/370 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.36); catalogued as rs758445296, COSV100554682, COSV59008592; called by muse, mutect2, varscan2
- TLN2 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60887511, COSV60891001; called by muse, mutect2, varscan2
- TMTC2 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as rs777976259; called by muse, mutect2, varscan2
- TUBA3C | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as rs201122043; called by muse, varscan2
- BAHCC1 | c.6927_6928insAGGGAGAGCGGCATGCCTGGGCCCATC p.A2309_E2310insRESGMPGPI | In Frame Ins (INS) | VAF 106/560 reads (19%) | called by pindel, varscan2
- IDE | c.2023del p.A675Lfs*15 | Frame Shift Del (DEL) | VAF 109/294 reads (37%) | called by mutect2, pindel, varscan2
- ROBO2 | c.3712G>T p.D1238Y | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- TRGV9 | c.364_366delinsCCGGCCGGGTTCGATTTTT p.V122Pfs*? | Frame Shift Ins (INS) | VAF 55/77 reads (71%) | called by pindel, varscan2*
- UBAC1 | c.857_858insCCATA p.E286Dfs*14 | Frame Shift Ins (INS) | VAF 117/322 reads (36%) | called by mutect2, pindel, varscan2
- PCDHB15 | c.1857G>A p.A619= | Silent (SNP) | VAF 36/1074 reads (3%) | catalogued as rs1217877580, COSV50865650; called by muse, mutect2
